Somatic mutation profile of tumor specimen 0DAN63 from CCDI case PBBJBJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 20.0 years (7,319 days).
Specimen 0DAN63: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b56aa878-3e06-4abd-8eb1-9720297315ab.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAN5X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36d1d831-9931-4cc5-a938-7dcc39015da5

The open-access MAF lists 50 somatic variants for this specimen: 29 protein-altering or splice-affecting, 13 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 13, 5'UTR 3, Intron 2, Nonsense Mutation 2, Frame Shift Del 2, 5'Flank 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.1591C>T p.Q531* | Nonsense Mutation (SNP) | VAF 762/1642 reads (46%) | catalogued as rs1057518134, CX072645; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CACNA1H | c.2231G>A p.R744Q | Missense Mutation (SNP) | VAF 78/543 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs373764821, CM032207; called by muse, mutect2, varscan2
- DCAF8L2 | c.1592G>A p.S531N | Missense Mutation (SNP) | VAF 96/437 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs764872814; called by muse, mutect2, varscan2
- EFCAB2 | c.338G>A p.S113N (on ENST00000366522; = p.S36N on NM_001290327.2) | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as rs1400264076; called by mutect2, varscan2
- FYB1 | c.277G>A p.G93R | Missense Mutation (SNP) | VAF 114/1076 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs184468828; called by muse, mutect2, varscan2
- GPR149 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 104/681 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67669414; called by muse, mutect2, varscan2
- HUWE1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 117/1172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99473667; called by muse, mutect2, varscan2
- JAKMIP1 | c.2254G>A p.E752K | Missense Mutation (SNP) | VAF 148/1003 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs1285016699; called by muse, mutect2, varscan2
- NBEAL2 | c.6128G>A p.R2043Q | Missense Mutation (SNP) | VAF 169/601 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as rs377667217; called by muse, mutect2, varscan2
- OR2Z1 | c.811G>T p.D271Y | Missense Mutation (SNP) | VAF 50/311 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100136492; called by muse, mutect2, varscan2
- SGSM1 | c.2626G>A p.E876K (on ENST00000400359 / NM_001039948.4; = p.E815K on NM_133454.3) | Missense Mutation (SNP) | VAF 257/821 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs747803377, COSV100771880; called by muse, mutect2, varscan2
- SLIT2 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 134/1024 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.589); catalogued as rs749945090; called by muse, mutect2, varscan2
- VSIG4 | c.1166A>T p.E389V | Missense Mutation (SNP) | VAF 240/919 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV66073707; called by muse, mutect2, varscan2
- WDR88 | c.1394C>T p.P465L | Missense Mutation (SNP) | VAF 104/686 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV63451213; called by muse, mutect2, varscan2
- ABCB11 | c.2978T>C p.F993S | Missense Mutation (SNP) | VAF 168/807 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BEND2 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 129/735 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- CD163 | c.1112T>C p.L371P | Missense Mutation (SNP) | VAF 200/477 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FSTL5 | c.888C>A p.D296E | Missense Mutation (SNP) | VAF 140/545 reads (26%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.76); called by mutect2, varscan2
- IL17RC | c.1040G>A p.W347* (on ENST00000295981 / NM_153461.4; = p.W261* on NM_032732.6 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 92/758 reads (12%) | called by muse, mutect2, varscan2
- LENG8 | c.1836_1845del p.Q613Afs*75 | Frame Shift Del (DEL) | VAF 66/416 reads (16%) | called by mutect2, varscan2
- MAL | c.452A>T p.K151M | Missense Mutation (SNP) | VAF 40/1384 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PARPBP | c.922G>C p.D308H | Missense Mutation (SNP) | VAF 44/1785 reads (2%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2
- PTPRH | c.1359del p.S454Lfs*25 | Frame Shift Del (DEL) | VAF 70/388 reads (18%) | called by mutect2, varscan2
- ROS1 | c.5486G>T p.R1829I | Missense Mutation (SNP) | VAF 336/1243 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SLC16A12 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT tolerated, low confidence (0.41); PolyPhen probably damaging (0.955); called by muse, mutect2
- STXBP5L | c.297A>C p.R99S | Missense Mutation (SNP) | VAF 32/800 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.115); called by muse, mutect2
- TIPARP | c.1969A>C p.I657L | Missense Mutation (SNP) | VAF 196/883 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ZEB2 | c.2609C>T p.S870L | Missense Mutation (SNP) | VAF 30/950 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2
- ZXDB | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 246/853 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- ADGRV1 | c.15579C>A p.V5193= | Silent (SNP) | VAF 112/669 reads (17%) | called by muse, varscan2
- AHRR | c.1269G>A p.P423= | Silent (SNP) | VAF 282/536 reads (53%) | catalogued as rs1212030931; called by muse, mutect2, varscan2
- ANK3 | c.1428C>T p.S476= | Silent (SNP) | VAF 135/806 reads (17%) | catalogued as rs535590655, COSV55062235; called by muse, mutect2, varscan2
- CD163L1 | c.1794G>A p.V598= | Silent (SNP) | VAF 149/1105 reads (13%) | called by muse, mutect2, varscan2
- FAM120C | c.375G>A p.A125= | Silent (SNP) | VAF 87/563 reads (15%) | catalogued as COSV60260184; called by muse, mutect2, varscan2
- GPR149 | c.1038C>T p.F346= | Silent (SNP) | VAF 111/791 reads (14%) | catalogued as COSV67665517, COSV67666666; called by muse, mutect2, varscan2
- INTS6L | c.540T>A p.S180= | Silent (SNP) | VAF 378/1306 reads (29%) | called by muse, mutect2, varscan2
- NT5DC4 | c.612G>T p.L204= | Silent (SNP) | VAF 97/569 reads (17%) | catalogued as rs760475762; called by muse, mutect2, varscan2
- NUP153 | c.1242C>T p.P414= | Silent (SNP) | VAF 134/1036 reads (13%) | catalogued as rs541758344; called by muse, mutect2, varscan2
- PLEKHS1 | c.948C>T p.S316= (on ENST00000369310 / NM_182601.1; = p.S336= on NM_024889.5) | Silent (SNP) | VAF 156/1023 reads (15%) | called by muse, mutect2, varscan2
- RYR3 | c.2017C>T p.L673= | Silent (SNP) | VAF 73/561 reads (13%) | called by muse, mutect2, varscan2
- TMEM151B | c.1329G>A p.S443= | Silent (SNP) | VAF 71/575 reads (12%) | called by muse, mutect2, varscan2
- ZNF583 | c.114C>T p.N38= | Silent (SNP) | VAF 86/531 reads (16%) | called by muse, mutect2, varscan2
- CALM3 | c.-55del | 5'UTR (DEL) | VAF 51/230 reads (22%) | called by mutect2, varscan2
- CEBPZ | c.2604-74G>T | Intron (SNP) | VAF 17/45 reads (38%) | catalogued as rs1283461058; called by muse, mutect2, varscan2
- KRTAP10-9 | c.*48C>T | 3'UTR (SNP) | VAF 281/613 reads (46%) | called by muse, mutect2, varscan2
- MAGEB6 | c.-40C>T | 5'UTR (SNP) | VAF 95/540 reads (18%) | called by muse, mutect2, varscan2
- OSBP2 | chr22:30694248 G>C | 5'Flank (SNP) | VAF 68/487 reads (14%) | catalogued as COSV60243405; called by muse, mutect2, varscan2
- OSBP2 | chr22:30694249 C>T | 5'Flank (SNP) | VAF 68/499 reads (14%) | called by muse, mutect2, varscan2
- SLC38A2 | c.-11C>T | 5'UTR (SNP) | VAF 32/362 reads (9%) | catalogued as COSV99874020; called by muse, mutect2
- TSPAN17 | c.818+86C>T | Intron (SNP) | VAF 15/119 reads (13%) | catalogued as rs540849895; called by muse, mutect2, varscan2
